Surgical pathology report (de-identified scan), TCGA case TCGA-BB-4225, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-4225-01A (Primary Tumor).

[REDACTED]
[REDACTED]
URG PATH REPORT

LECTION DATE/TIME: [REDACTED]

FINAL DIAGNOSIS

Pathologist: [REDACTED]

TONGUE, RIGHT BASE (EXCISION): INVASIVE, POORLY DIFFERENTIATED
SQUAMOUS CELL CARCINOMA.

[REDACTED] TCGA-BB-4225

* Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file 248ed14f-1e06-4762-9d66-d0aeff0d14fe (TCGA-BB-4225.709D27DF-B8D5-4D89-AD96-6F08CFA89736.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).